MMRF case MMRF_1876 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d090e639-9e47-4e8d-b8d1-433bdaf1e148

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Dead; Days to death: 600 days (1.6 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.1 years (25,611 days); ISS stage: III; Days to last known disease status: 600 days (1.6 years); Days to last follow up: 600 days (1.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 85 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 149 days; Days to treatment end: 149 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 239 days; Days to treatment end: 490 days (1.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 490 days (1.3 years); Days to treatment end: 564 days (1.5 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 600.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 1): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.42 mg/dL; Immunoglobulin G 42.1 g/L; Immunoglobulin A 0.255 g/L; Immunoglobulin M 0.252 g/L; Beta 2 Microglobulin 5.8 µg/mL; Lactate Dehydrogenase 4.7 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 9.4 g/dL; Glucose 7.98 mmol/L.
- Day 57 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 2.55 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.368 g/L; Lactate Dehydrogenase 4.2 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 7.26 mmol/L.
- Day 183 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 5.06 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.499 g/L; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 6.05 mmol/L.
- Day 276 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.1 mg/dL; Immunoglobulin G 5.96 g/L; Immunoglobulin A 0.734 g/L; Immunoglobulin M 0.677 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 12.1 ×10⁹/L; Absolute Neutrophil 9.2 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 6.22 mmol/L.
- Day 445: M Protein 1.06 g/dL; Hemoglobin 6.08 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 5.83 mmol/L.
- Day 505 (ECOG 0): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.8 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 0.359 g/L; Immunoglobulin M 0.205 g/L; Lactate Dehydrogenase 7.22 µkat/L; Hemoglobin 5.33 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 104 ×10⁹/L; Creatinine 142 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6.8 g/dL; Glucose 5.83 mmol/L.

Other clinical attributes
- Day 0: Weight: 58 kg; Height: 153 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Maternal Grandfather; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1876_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1876_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
